Gene-level copy-number profile of tumor specimen TCGA-27-2519-01A from TCGA case TCGA-27-2519, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.5 years (17,715 days).
Specimen TCGA-27-2519-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.283d599c-0177-49b1-9479-af035ba69f8b.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-27-2519-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 375 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80d4d116-e10a-4337-bd38-0c08c507c98b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 13,905; copy number 2: 33,771; copy number 3: 8,429; copy number 4: 4,139; copy number 6: 1; copy number 13: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-27-2519-01A-01D-0784-01): tumor purity 0.7, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:29,775,504–29,824,312, 2 genes, copy number 13: AC008798.3, CCNE1.
- chr19:34,576,733–34,577,701, 1 gene, copy number 6: SCGB1B2P.

Autosomal genes at a single copy (total copy number 1): 11,525. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
